Somatic mutation profile of tumor specimen TARGET-40-PATMIF-01A (aliquot TARGET-40-PATMIF-01A-01Y) from TARGET case TARGET-40-PATMIF, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 12.0 years (4,383 days).
Specimen TARGET-40-PATMIF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f42fe061-4f6e-4a79-b0e5-8d5c32f819ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PATMIF-10A (Blood Derived Normal), aliquot TARGET-40-PATMIF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef38679f-7d95-4e60-9d33-d098fc817e7c

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERICH3 | c.4283A>T p.E1428V | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by mutect2, varscan2
- PAMR1 | c.1315G>C p.A439P (on ENST00000619888 / NM_001001991.3; = p.A456P on NM_015430.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.99); called by muse, mutect2
- PLPP5 | c.323A>C p.K108T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TENM1 | c.5006G>C p.G1669A | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ZNF780A | c.1332T>C p.P444= | Silent (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
